Somatic mutation profile of tumor specimen 8120e7d6-bd09-4334-841c-70a214 (aliquot 8120e7d6-bd09-4334-841c-70a214_D6) from CPTAC case 02OV006, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen 8120e7d6-bd09-4334-841c-70a214: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70098b90-1314-418c-88b6-6b860a8751bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 45698791-f0d6-4ab7-9b4a-3d8bf4 (Blood Derived Normal), aliquot 45698791-f0d6-4ab7-9b4a-3d8bf4_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77634860-95b9-490b-b121-bb75f2aaeefe

The open-access MAF lists 197 somatic variants for this specimen: 131 protein-altering or splice-affecting, 42 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 42, Intron 10, 3'UTR 8, Splice Site 7, Frame Shift Del 6, Nonsense Mutation 5, 5'UTR 3, In Frame Del 2, Splice Region 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.5422G>A p.G1808S | Missense Mutation (SNP) | VAF 323/646 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs369940645, CM1310646; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.920-1G>T p.X307_splice | Splice Site (SNP) | VAF 155/225 reads (69%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2767A>T p.T923S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.883); catalogued as CM042273; called by muse, mutect2, varscan2
- ALS2 | c.4201G>T p.V1401L | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762372365; called by mutect2, varscan2
- AMDHD1 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs755301280, COSV57138728; called by muse, mutect2, varscan2
- ATP11C | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 164/278 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59566490; called by muse, mutect2, varscan2
- AVPR2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs782106562; called by muse, mutect2, varscan2
- CBY2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs372471800; called by muse, mutect2, varscan2
- CLPTM1 | c.1152C>A p.S384R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV61611414; called by muse, mutect2, varscan2
- CNTN4 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs896789494, COSV61876875, COSV61878084; called by muse, mutect2
- DNAJC16 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs969299936; called by muse, mutect2, varscan2
- DZIP1 | c.2005C>T p.P669S (on ENST00000347108; = p.P650S on NM_014934.5) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs761770434, COSV61271752; called by muse, mutect2, varscan2
- EME1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746533275; called by muse, mutect2, varscan2
- FRY | c.5938C>T p.R1980* | Nonsense Mutation (SNP) | VAF 29/112 reads (26%) | catalogued as rs1054081832, COSV66568362; called by muse, mutect2, varscan2
- GBP5 | c.1716C>G p.H572Q | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.042); catalogued as COSV58594140; called by muse, mutect2, varscan2
- HTR5A | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs759280641; called by muse, mutect2, varscan2
- IGHE | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs537389853; called by muse, mutect2, varscan2
- IGSF1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 276/459 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as COSV63836609, COSV63839040; called by muse, mutect2, varscan2
- KDM6B | c.1668C>A p.S556R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs770165612; called by muse, mutect2, varscan2
- LDLR | c.1175G>A p.C392Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060500986; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LRRC41 | c.2200C>G p.L734V | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs780586234; called by muse, mutect2, varscan2
- LRRN1 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs748127160, COSV60012270; called by muse, mutect2, varscan2
- MSH5 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV65209714; called by muse, mutect2, varscan2
- MYO1D | c.2762C>T p.T921M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs776654965, COSV59019143; called by muse, mutect2, varscan2
- MYOCD | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs760467742; called by muse, mutect2, varscan2
- PANX3 | c.894C>G p.D298E | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV104370660; called by muse, mutect2
- PAX9 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 54/338 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1311113788; called by muse, mutect2, varscan2
- PCDHA8 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65336618; called by muse, mutect2
- PCSK5 | c.5438G>A p.R1813Q | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs533035572, COSV70447802; called by muse, mutect2, varscan2
- PLA2G1B | c.446G>C p.*149Sext*20 | Nonstop Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as rs923720236; called by muse, mutect2, varscan2
- PTCD3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139051130; called by mutect2, varscan2
- RAD51AP2 | c.3189T>A p.N1063K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV101208370; called by muse, mutect2, varscan2
- RBCK1 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs779329081; called by muse, mutect2, varscan2
- RIMS1 | c.4795A>T p.T1599S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99330343; called by muse, mutect2, varscan2
- SEMA5B | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as rs753696390, COSV52110156; called by mutect2, varscan2
- SGK3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 96/155 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1357035961; called by muse, mutect2, varscan2
- SGSM1 | c.200G>C p.S67T | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as rs1172133003; called by muse, mutect2, varscan2
- SMAD4 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100748076, COSV61684586; called by muse, mutect2, varscan2
- SPHKAP | c.4183A>T p.N1395Y | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV60876242; called by muse, mutect2, varscan2
- TMEM82 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1382105723; called by muse, mutect2, varscan2
- TPX2 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55919754; called by muse, mutect2
- USH2A | c.14969C>T p.T4990I | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs748417644; called by muse, mutect2, varscan2
- ADAM33 | c.359dup p.R121Kfs*226 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- AMER3 | c.1769A>T p.Q590L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APC | c.5814del p.D1939Tfs*31 | Frame Shift Del (DEL) | VAF 57/171 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP10 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARPC4 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- BDP1 | c.4735C>T p.P1579S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BRMS1L | c.877del p.H293Mfs*39 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | called by mutect2, pindel, varscan2
- C1orf35 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- C2orf68 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.188); called by mutect2, varscan2
- C2orf68 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CACNA1E | c.964_972del p.L322_A324del | In Frame Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- CADPS | c.1334C>G p.T445S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CAMSAP2 | c.2417G>T p.G806V (on ENST00000236925 / NM_001297707.2; = p.G795V on NM_203459.3) | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CCDC185 | c.1214G>A p.C405Y | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CD151 | c.84G>C p.W28C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP104 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2
- CHRNG | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by mutect2, varscan2
- CKMT1B | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCN2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLMN | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2
- CNTN6 | c.358+3_358+13del p.X120_splice | Splice Site (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1087A>G p.N363D | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CXCL5 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CXCR3 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- CYP4V2 | c.326A>T p.E109V | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- D2HGDH | c.533G>C p.S178T | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCPS | c.376+1G>C p.X126_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- DDX5 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- DNAH1 | c.8938G>C p.E2980Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- DPPA3 | c.305T>A p.M102K | Missense Mutation (SNP) | VAF 66/591 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EDEM1 | c.448_453del p.F150_P151del | In Frame Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ELFN1 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FLNB | c.6295A>G p.I2099V | Missense Mutation (SNP) | VAF 131/417 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GOLGA6L10 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 50/1166 reads (4%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.699); called by muse, mutect2
- GRIN2D | c.1496T>C p.I499T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- GTF3C5 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTPBP8 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- H4C8 | c.88_116del p.I30Sfs*14 | Frame Shift Del (DEL) | VAF 19/189 reads (10%) | called by mutect2, pindel
- INSM2 | c.778_797del p.L260Afs*29 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- INTS6L | c.331_339+8del p.X111_splice | Splice Site (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- IQSEC3 | c.999G>C p.K333N (on ENST00000538872 / NM_001170738.2; = p.K30N on NM_015232.1) | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- IRF1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNMB1 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.174); called by muse, mutect2
- KIAA0100 | c.6224A>G p.K2075R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2E | c.2579A>G p.D860G | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD6 | c.296T>A p.L99Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MDGA1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED14 | c.2538C>G p.N846K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MFSD4A | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MMP27 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYADML2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH7 | c.2786A>G p.E929G | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPAS4 | c.1914G>C p.Q638H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NPHP4 | c.802T>G p.F268V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.058); called by mutect2, varscan2
- NPRL3 | c.493C>T p.R165W (on ENST00000611875 / NM_001077350.3; = p.R140W on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NWD2 | c.5087T>C p.V1696A | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PACS1 | c.1764G>T p.K588N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PAX9 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCED1B | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCSK1 | c.1885-2A>C p.X629_splice | Splice Site (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- PIGQ | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PLXNA2 | c.5197G>C p.D1733H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- POLE2 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPM1E | c.65T>A p.F22Y | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PRM3 | c.91T>A p.S31T | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by mutect2, varscan2
- RAB5C | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RIMS2 | c.857A>T p.E286V (on ENST00000666250 / NM_001348490.2; = p.E94V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- RPTN | c.164_197del p.E55Vfs*24 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel
- RTL8C | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCN9A | c.2329G>A p.A777T (on ENST00000303354; = p.A766T on NM_002977.3) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC31A | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SLC25A23 | c.798C>A p.I266= | Splice Region (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- SLFN12 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SLITRK1 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- SMCHD1 | c.186G>A p.Q62= | Splice Region (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- SOX21 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX6 | c.490T>A p.L164M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SYNPO | c.400+1G>T p.X134_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- TBK1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMTC2 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TRAPPC8 | c.1653C>G p.N551K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UBE2U | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- UBR2 | c.5127-1G>C p.X1709_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- UNKL | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- ZBTB10 | c.2556del p.Q853Rfs*17 (on ENST00000430430; = p.Q829Rfs*17 on NM_023929.4) | Frame Shift Del (DEL) | VAF 19/183 reads (10%) | called by mutect2, pindel, varscan2
- ZBTB16 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.07); called by mutect2, varscan2
- ZC3HAV1 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF774 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.1590C>T p.G530= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs751451715; called by muse, mutect2, varscan2
- APMAP | c.975T>C p.P325= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- APOB | c.9472T>C p.L3158= | Silent (SNP) | VAF 74/353 reads (21%) | called by muse, mutect2, varscan2
- BIRC3 | c.819T>C p.P273= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- C1orf35 | c.315G>A p.R105= | Silent (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2
- C8orf82 | c.33G>T p.L11= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- CACNA1H | c.1176A>C p.S392= | Silent (SNP) | VAF 42/124 reads (34%) | called by muse, mutect2, varscan2
- CFHR1 | c.294A>G p.E98= | Silent (SNP) | VAF 66/242 reads (27%) | catalogued as rs772361407; called by muse, mutect2, varscan2
- COL2A1 | c.2559G>A p.E853= | Silent (SNP) | VAF 177/546 reads (32%) | catalogued as rs770939212; called by muse, mutect2, varscan2
- CPQ | c.1161G>A p.E387= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs1332634621; called by muse, mutect2, varscan2
- CSMD1 | c.9429G>T p.V3143= (on ENST00000520002; = p.V3142= on NM_033225.6) | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- FADS1 | c.798C>A p.A266= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- FFAR1 | c.114C>G p.L38= | Silent (SNP) | VAF 30/204 reads (15%) | called by muse, mutect2, varscan2
- GIT1 | c.516C>T p.H172= | Silent (SNP) | VAF 32/247 reads (13%) | catalogued as rs200538739; called by muse, mutect2, varscan2
- GUCY1A1 | c.1332G>A p.E444= | Silent (SNP) | VAF 72/285 reads (25%) | catalogued as COSV56651838, COSV99637255; called by muse, mutect2, varscan2
- ITGA1 | c.2577G>A p.V859= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- KCNQ1 | c.300G>T p.V100= | Silent (SNP) | VAF 53/198 reads (27%) | called by muse, mutect2, varscan2
- KDM8 | c.570G>A p.P190= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs760068379, COSV53729255; called by muse, mutect2, varscan2
- KHNYN | c.1218G>C p.G406= | Silent (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- LMAN2L | c.255C>A p.I85= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs1230268732; called by muse, mutect2, varscan2
- LRRC40 | c.1608G>A p.Q536= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- LRRC8D | c.888C>A p.A296= | Silent (SNP) | VAF 56/200 reads (28%) | called by mutect2, varscan2
- MPO | c.1935C>A p.G645= | Silent (SNP) | VAF 103/157 reads (66%) | called by muse, mutect2, varscan2
- OR2J2 | c.768C>G p.V256= | Silent (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- OR2M5 | c.153G>T p.L51= | Silent (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- OR4C3 | c.267C>T p.T89= | Silent (SNP) | VAF 17/192 reads (9%) | catalogued as COSV60590994; called by muse, mutect2
- PLSCR2 | c.486T>C p.T162= (on ENST00000497985 / NM_001199978.1; = p.T89= on NM_020359.2) | Silent (SNP) | VAF 12/315 reads (4%) | called by muse, mutect2
- PRRX1 | c.363T>A p.A121= | Silent (SNP) | VAF 44/261 reads (17%) | called by muse, mutect2, varscan2
- PSG1 | c.255C>T p.D85= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1058959, COSV54944619, COSV54949080; called by muse, mutect2, varscan2
- SETBP1 | c.576T>C p.H192= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV56324330; called by muse, mutect2, varscan2
- SETBP1 | c.1449T>A p.G483= | Silent (SNP) | VAF 100/419 reads (24%) | called by muse, mutect2, varscan2
- SLFN12 | c.153G>T p.L51= | Silent (SNP) | VAF 62/126 reads (49%) | called by mutect2, varscan2
- SPDEF | c.751C>T p.L251= | Silent (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- SPPL2A | c.132T>C p.L44= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- SRSF6 | c.225C>T p.R75= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs1282682333; called by muse, mutect2, varscan2
- SV2B | c.1422T>C p.F474= | Silent (SNP) | VAF 53/307 reads (17%) | called by muse, mutect2, varscan2
- TAC1 | c.183T>A p.P61= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- TELO2 | c.1218C>T p.G406= | Silent (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- TMEM229B | c.153C>T p.F51= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- ULK2 | c.2688G>A p.A896= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs756054494; called by muse, mutect2, varscan2
- USH2A | c.14070T>C p.Y4690= | Silent (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2, varscan2
- ZFAT | c.2385C>T p.N795= | Silent (SNP) | VAF 44/330 reads (13%) | called by muse, mutect2, varscan2
- AC008060.1 | n.347A>G | RNA (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ANKRD36 | c.-8C>G | 5'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- CAD | c.4315-10C>A | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as rs1479253081; called by muse, mutect2, varscan2
- CENPO | c.-116G>C | 5'UTR (SNP) | VAF 10/65 reads (15%) | catalogued as rs769947918, COSV99579336; called by muse, mutect2, varscan2
- DUSP13 | c.*578A>T | 3'UTR (SNP) | VAF 38/322 reads (12%) | called by mutect2, varscan2
- EEF1D | c.*18G>A | 3'UTR (SNP) | VAF 12/63 reads (19%) | catalogued as rs752731167; called by muse, mutect2, varscan2
- GAPDH | c.-23-25C>G | Intron (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- GCNT7 | c.-76C>G | 5'UTR (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- GRIA3 | c.508+36C>G | Intron (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*1479G>A | 3'UTR (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- MMP14 | c.108+438C>A | Intron (SNP) | VAF 50/257 reads (19%) | catalogued as rs900388559, COSV100314020; called by muse, mutect2, varscan2
- MPRIP | c.2163+3977C>G | Intron (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- PATZ1 | chr22:31346969 C>A | 5'Flank (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- PHYH | c.*36C>G | 3'UTR (SNP) | VAF 40/245 reads (16%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.-40+11331del | Intron (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- POM121 | chr7:72948741 G>C | 3'Flank (SNP) | VAF 30/247 reads (12%) | called by muse, mutect2, varscan2
- PPP2R3C | c.502+29C>T | Intron (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- RARA | c.*282C>T | 3'UTR (SNP) | VAF 8/96 reads (8%) | catalogued as rs1448063021; called by muse, mutect2
- SCGB1D1 | c.*16T>G | 3'UTR (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2
- SCLT1 | c.235-1116G>T | Intron (SNP) | VAF 22/164 reads (13%) | called by mutect2, varscan2
- SIRPB1 | c.76+14958G>A | Intron (SNP) | VAF 152/227 reads (67%) | called by muse, mutect2, varscan2
- THSD4 | c.*3364C>G | 3'UTR (SNP) | VAF 256/357 reads (72%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*634G>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- TTC7B | c.699-3637A>G | Intron (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
